Somatic mutation profile of tumor specimen TCGA-DU-A7TD-01A (aliquot TCGA-DU-A7TD-01A-12D-A34A-08) from TCGA case TCGA-DU-A7TD, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 52.1 years (19,025 days).
Specimen TCGA-DU-A7TD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2f9165b3-8769-4e22-b35f-86875e2b05c1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DU-A7TD-10A (Blood Derived Normal), aliquot TCGA-DU-A7TD-10A-01D-A34A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0567b082-5c8b-42b3-8a94-ab5657be3d7b

The open-access MAF lists 52 somatic variants for this specimen: 35 protein-altering or splice-affecting, 13 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 13, Intron 2, Frame Shift Del 1, RNA 1, Splice Region 1, 5'UTR 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC068580.4 | c.743G>T p.G248V | Missense Mutation (SNP) | VAF 49/115 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV99362535; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.1285A>C p.K429Q | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.412); catalogued as COSV100416928; called by muse, mutect2, varscan2
- AMOTL1 | c.715G>A p.A239T | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.177); catalogued as COSV100133920; called by muse, mutect2, varscan2
- CAGE1 | c.1301C>T p.S434F (on ENST00000512086; = p.S298F on NM_205864.3) | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.61); catalogued as COSV57075747; called by muse, mutect2, varscan2
- CD1E | c.223C>T p.R75C | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.768); catalogued as rs200189250, COSV100936901; called by muse, mutect2, varscan2
- CIT | c.4160G>A p.R1387H | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.991); catalogued as rs140614337; called by muse, mutect2, varscan2
- EGFR | c.827A>T p.Q276L | Missense Mutation (SNP) | VAF 2482/2563 reads (97%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.721); catalogued as COSV99294781; called by muse, mutect2, varscan2
- ESCO1 | c.2369G>A p.C790Y | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99332567; called by muse, mutect2, varscan2
- EXTL2 | c.376C>A p.Q126K | Missense Mutation (SNP) | VAF 60/111 reads (54%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.796); catalogued as COSV100921139; called by muse, mutect2, varscan2
- GIMAP8 | c.766C>T p.R256C | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs576578780, COSV56231919; called by muse, mutect2, varscan2
- HEY1 | c.526G>A p.G176R | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.51); catalogued as rs779415991, COSV100559294; called by muse, mutect2, varscan2
- KIF1B | c.5423G>A p.R1808H (on ENST00000377086 / NM_001365952.1; = p.R1762H on NM_015074.3) | Missense Mutation (SNP) | VAF 73/204 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs770215708, COSV55806544; called by muse, mutect2, varscan2
- LPIN2 | c.2090C>T p.S697L | Missense Mutation (SNP) | VAF 33/74 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754622332, COSV99858952; called by muse, mutect2, varscan2
- MBL2 | c.712A>T p.T238S | Missense Mutation (SNP) | VAF 122/194 reads (63%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs755866544, COSV100906409, COSV64759505; called by mutect2, varscan2
- NLGN4X | c.2081C>T p.A694V | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1488114392, COSV52017265; called by muse, mutect2
- NLRP2 | c.3040C>T p.R1014W | Missense Mutation (SNP) | VAF 47/123 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.696); catalogued as rs996672212, COSV54756086; called by muse, mutect2, varscan2
- NOXO1 | c.454T>C p.S152P (on ENST00000397280 / NM_172168.3; = p.S146P on NM_144603.4) | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV99937103; called by muse, mutect2
- OR11L1 | c.11A>G p.Q4R | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV100869487; called by muse, mutect2
- OR6B3 | c.296C>T p.T99M | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); catalogued as rs765260499, COSV100097645; called by muse, mutect2, varscan2
- PCDHGB7 | c.151G>A p.A51T | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as COSV54013177, COSV99546438; called by muse, mutect2, varscan2
- PEX1 | c.272A>G p.Q91R | Missense Mutation (SNP) | VAF 64/345 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs769954130, COSV99952356; called by muse, mutect2, varscan2
- PLCG2 | c.2350C>T p.R784* | Nonsense Mutation (SNP) | VAF 11/30 reads (37%) | catalogued as rs1567534502, COSV100842231; called by muse, mutect2, varscan2
- POLRMT | c.2456A>T p.D819V | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99242292; called by muse, mutect2, varscan2
- PTEN | c.1026G>A p.K342= | Splice Region (SNP) | VAF 45/64 reads (70%) | catalogued as rs398123314, CM132269, COSV100911310, COSV64292596, COSV64307072; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- REEP2 | c.658G>A p.A220T | Missense Mutation (SNP) | VAF 3/50 reads (6%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs868536652, COSV99649757; called by muse, mutect2
- SLC28A2 | c.1153G>A p.E385K | Missense Mutation (SNP) | VAF 69/171 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.232); catalogued as rs376327143, CM074558, COSV100754810; called by muse, mutect2, varscan2
- SLCO1B1 | c.721G>A p.D241N | Missense Mutation (SNP) | VAF 58/138 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.557); catalogued as rs751709893, CM087803, COSV57006574, COSV99919096; called by muse, mutect2, varscan2
- SNED1 | c.2203C>T p.R735C | Missense Mutation (SNP) | VAF 43/109 reads (39%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.517); catalogued as COSV100123388; called by muse, mutect2, varscan2
- STRC | c.4627C>A p.L1543I | Missense Mutation (SNP) | VAF 43/109 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100294685; called by muse, mutect2, varscan2
- TMEM259 | c.673G>A p.A225T | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.22); PolyPhen benign (0.088); catalogued as COSV99312874; called by muse, mutect2
- TNFSF14 | c.653G>A p.R218H | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs150171386; called by muse, mutect2, varscan2
- TNP1 | c.128G>A p.R43Q | Missense Mutation (SNP) | VAF 48/145 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.89); catalogued as rs367585957; called by muse, mutect2, varscan2
- IGHV3-20 | c.118T>A p.S40T | Missense Mutation (SNP) | VAF 59/174 reads (34%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- PCDHB9 | c.2025G>T p.E675D | Missense Mutation (SNP) | VAF 84/329 reads (26%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- RPS6KA1 | c.1554del p.I519Lfs*18 | Frame Shift Del (DEL) | VAF 23/87 reads (26%) | called by mutect2, pindel, varscan2
- ACACB | c.2973A>G p.K991= | Silent (SNP) | VAF 62/170 reads (36%) | catalogued as COSV100623286; called by muse, mutect2, varscan2
- BPIFB2 | c.609C>T p.I203= | Silent (SNP) | VAF 13/81 reads (16%) | catalogued as COSV99401669; called by muse, mutect2, varscan2
- DLK1 | c.1140C>T p.D380= | Silent (SNP) | VAF 24/83 reads (29%) | catalogued as rs1555410480, COSV57991742; called by muse, mutect2, varscan2
- GALNS | c.1263G>A p.G421= | Silent (SNP) | VAF 3/45 reads (7%) | catalogued as rs1365302379, COSV99243443; called by muse, mutect2
- IL18RAP | c.345C>T p.T115= | Silent (SNP) | VAF 40/105 reads (38%) | catalogued as rs775331372, COSV99962396; called by muse, mutect2, varscan2
- PCLO | c.13470C>T p.Y4490= | Silent (SNP) | VAF 44/187 reads (24%) | catalogued as COSV100437536; called by muse, mutect2, varscan2
- PTPN5 | c.132C>T p.D44= | Silent (SNP) | VAF 67/150 reads (45%) | catalogued as rs367543233, COSV62128918; ClinVar: not provided; called by muse, mutect2, varscan2
- RFPL2 | c.738C>T p.D246= | Silent (SNP) | VAF 51/129 reads (40%) | catalogued as rs749206718, COSV99964579; called by muse, mutect2, varscan2
- SLC5A4 | c.1890G>A p.T630= | Silent (SNP) | VAF 44/110 reads (40%) | catalogued as rs755419066, COSV99832130; called by muse, mutect2, varscan2
- SSTR3 | c.219G>A p.T73= | Silent (SNP) | VAF 75/151 reads (50%) | catalogued as rs550210765, COSV60729706; called by muse, mutect2, varscan2
- VPS54 | c.528C>A p.S176= | Silent (SNP) | VAF 40/70 reads (57%) | catalogued as COSV99708704; called by muse, mutect2, varscan2
- VTA1 | c.627T>C p.Y209= | Silent (SNP) | VAF 23/59 reads (39%) | catalogued as COSV100859263; called by muse, mutect2, varscan2
- ZSCAN1 | c.207C>G p.P69= | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as rs780281468, COSV56602962; called by muse, varscan2
- ABHD5 | c.774-622C>T | Intron (SNP) | VAF 10/122 reads (8%) | catalogued as COSV68904804; called by muse, mutect2
- AC074085.2 | n.97C>T | RNA (SNP) | VAF 38/175 reads (22%) | catalogued as rs754890620; called by muse, mutect2, varscan2
- RASSF10 | c.-240G>T | 5'UTR (SNP) | VAF 10/18 reads (56%) | catalogued as rs370876528; called by muse, varscan2
- UGT1A6 | c.862-23132G>A | Intron (SNP) | VAF 9/42 reads (21%) | catalogued as rs770691045, COSV59383609; called by muse, mutect2
